Somatic mutation profile of tumor specimen TCGA-06-5413-01A (aliquot TCGA-06-5413-01A-01D-1696-08) from TCGA case TCGA-06-5413, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-06-5413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1374012e-dc3e-4940-a436-93f00388a4f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5413-10A (Blood Derived Normal), aliquot TCGA-06-5413-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac6480bd-d570-45a4-8592-fee769363dd6

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Frame Shift Del 2, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 50/79 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 38/97 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV55904673; called by muse, mutect2, varscan2
- AKAP1 | c.2068T>A p.S690T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.852); catalogued as COSV58470601; called by muse, mutect2, varscan2
- AMER3 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as rs749575852, COSV58467245; called by muse, mutect2, varscan2
- BBS12 | c.2114C>T p.T705M | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs372102223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD86 | c.830G>A p.R277H (on ENST00000330540 / NM_175862.5; = p.R271H on NM_006889.4) | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.266); catalogued as rs750874477, COSV52607274; called by muse, mutect2, varscan2
- CFAP74 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs772880951, COSV54568613; called by muse, mutect2, varscan2
- CTNNA3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776250185, COSV57718884, COSV57721946; called by muse, mutect2, varscan2
- DAGLB | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51704412; called by muse, mutect2, varscan2
- EIF4G3 | c.736C>G p.Q246E | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.054); catalogued as COSV51683608; called by muse, mutect2, varscan2
- FAT2 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | catalogued as rs765547953, COSV55818860; called by muse, mutect2, varscan2
- GCNT1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs656106, COSV65057049; called by muse, mutect2, varscan2
- HDLBP | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as COSV60496647; called by muse, mutect2, varscan2
- HM13 | c.525G>T p.W175C | Missense Mutation (SNP) | VAF 119/401 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV59437401; called by muse, mutect2, varscan2
- HUNK | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775412939, COSV54229059; called by muse, mutect2, varscan2
- IL3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV57309107; called by muse, mutect2, varscan2
- KLRD1 | c.392A>T p.E131V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60273793; called by muse, mutect2, varscan2
- LRP3 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV53504471; called by muse, mutect2, varscan2
- MPO | c.1283C>G p.T428R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56564545; called by muse, mutect2, varscan2
- NCR1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs759022000, COSV52555719; called by muse, mutect2, varscan2
- OR2A1 | c.302T>G p.F101C | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1487904193, COSV68822781; called by muse, mutect2
- OR4D9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs535085659, COSV61434513; called by muse, mutect2, varscan2
- PPEF2 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV54422893; called by muse, mutect2, varscan2
- PRKCB | c.544A>T p.N182Y | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57782080; called by muse, varscan2
- PTX4 | c.542G>A p.G181D (on ENST00000447419 / NM_001328608.2; = p.G176D on NM_001013658.1) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV53517009; called by muse, mutect2, varscan2
- RPL5 | c.15del p.V6Lfs*13 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as COSV59873719; called by mutect2, pindel, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- SERPINE1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV56169873; called by muse, mutect2, varscan2
- SETD1A | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52688259; called by muse, mutect2, varscan2
- SH2D1B | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63392295; called by muse, mutect2, varscan2
- SPNS1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57954965; called by muse, mutect2, varscan2
- TEP1 | c.5045T>C p.V1682A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV52993597; called by muse, mutect2, varscan2
- TTC17 | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV50009388; called by muse, mutect2, varscan2
- TTN | c.3242C>T p.A1081V (on ENST00000591111; = p.A1035V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | PolyPhen possibly damaging (0.794); catalogued as rs528216574, COSV59945196; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZPBP2 | c.236C>T p.T79M (on ENST00000348931 / NM_199321.3; = p.T57M on NM_198844.3) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs768553645, COSV62375318; called by muse, mutect2, varscan2
- CHD8 | c.6605_6615del p.S2202Wfs*5 (on ENST00000646647 / NM_001170629.2; = p.S1923Wfs*5 on NM_020920.4) | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.972dup p.N325Qfs*3 | Frame Shift Ins (INS) | VAF 54/122 reads (44%) | called by mutect2, pindel, varscan2
- ZNF605 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS12 | c.4230C>T p.G1410= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV61264457; called by muse, mutect2, varscan2
- APOB | c.11028C>T p.I3676= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51938043; called by muse, mutect2, varscan2
- BRPF3 | c.3024C>T p.S1008= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs752662552, COSV60207737; called by muse, mutect2, varscan2
- IL17RD | c.1413G>A p.A471= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs747651301, COSV56338744; called by muse, mutect2, varscan2
- LGSN | c.1071C>T p.C357= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as rs745545025, COSV65727402; called by muse, mutect2, varscan2
- MAPK10 | c.129G>A p.A43= (on ENST00000359221 / NM_001351625.2; = p.A81= on NM_002753.5) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs777812515, COSV100175529, COSV60374911; called by muse, mutect2, varscan2
- MRC1 | c.3918G>A p.T1306= | Silent (SNP) | VAF 60/116 reads (52%) | catalogued as rs782728662, COSV53471190; called by muse, mutect2, varscan2
- NISCH | c.3855G>A p.P1285= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs761604637, COSV58737205; called by muse, mutect2, varscan2
- PLK4 | c.753A>T p.A251= | Silent (SNP) | VAF 57/183 reads (31%) | catalogued as COSV54637738; called by muse, mutect2, varscan2
- SCN3A | c.1920A>G p.A640= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV51811790, COSV51812957; called by muse, mutect2, varscan2
- UBE3C | c.2835T>C p.N945= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV61953606; called by muse, mutect2, varscan2
- C9orf129 | n.704G>T | RNA (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100962250; called by muse, mutect2, varscan2
- SSPOP | n.7166G>A | RNA (SNP) | VAF 9/35 reads (26%) | catalogued as rs1262647935, COSV50487749; called by muse, mutect2, varscan2
